Somatic mutation profile of tumor specimen MP2PRT-PATCTI-TMP1-B (aliquot MP2PRT-PATCTI-TMP1-B-1-0-D-A83C-36) from MP2PRT case MP2PRT-PATCTI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,414 days).
Specimen MP2PRT-PATCTI-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71cdd5b3-887b-4b26-b45a-f9f6a4483f0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCTI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCTI-NB1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49ee7013-5db3-4873-8276-90b13b2a01cd

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPATC1 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 262/480 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs782182553, COSV101085167, COSV66298452; called by muse, mutect2, varscan2
- MYH14 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 198/452 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, varscan2
- MAN2B1 | c.2943T>C p.T981= | Silent (SNP) | VAF 187/402 reads (47%) | called by muse, mutect2, varscan2
